Somatic mutation profile of tumor specimen TARGET-30-PATRHD-01A (aliquot TARGET-30-PATRHD-01A-01D) from TARGET case TARGET-30-PATRHD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.9 years (2,534 days).
Specimen TARGET-30-PATRHD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 141bda4b-8d35-4f7a-9044-6cd728b82564.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATRHD-10A (Blood Derived Normal), aliquot TARGET-30-PATRHD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5c30a75-d303-47b6-bf10-516793ca5613

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPAP1 | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV61512459, COSV61513010; called by muse, mutect2, varscan2
- PPP6R3 | c.2039-1G>C p.X680_splice (on ENST00000393800 / NM_001352375.2; = p.X600_splice on NM_018312.5) | Splice Site (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
